Somatic mutation profile of tumor specimen 0DOG3E from CCDI case PBCCNC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.6 years (582 days).
Specimen 0DOG3E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f18374c-1eb7-4c8e-9e28-94eed10fd288.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOG30 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fa60b0b-4ca7-4464-a715-a3ae1912d557

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPP8 | c.580C>T p.P194S (on ENST00000341861 / NM_001320875.2; = p.P178S on NM_017743.6) | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV100202110; called by muse, mutect2, varscan2
- ZNF416 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 35/255 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as COSV99543934; called by muse, mutect2, varscan2
